Somatic mutation profile of tumor specimen TCGA-66-2744-01A (aliquot TCGA-66-2744-01A-01D-0983-08) from TCGA case TCGA-66-2744, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-66-2744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6da8bb94-26fc-4f36-b81e-6293d654bc66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2744-11A (Solid Tissue Normal), aliquot TCGA-66-2744-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b6bc109-2577-46e0-a07e-7a31fabf277b

The open-access MAF lists 214 somatic variants for this specimen: 171 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 37, Nonsense Mutation 14, Frame Shift Del 9, Intron 3, Splice Region 2, Splice Site 2, RNA 2, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3860C>A p.A1287D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV55590168; called by muse, mutect2, varscan2
- ADAM18 | c.1417C>G p.P473A | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV55847260; called by muse, mutect2, varscan2
- ADGRB3 | c.2709G>C p.W903C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53244162; called by muse, mutect2
- ADGRL3 | c.2872G>A p.V958I (on ENST00000506720 / NM_001322402.2; = p.V890I on NM_015236.6) | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.823); catalogued as COSV72230535; called by muse, mutect2, varscan2
- AGAP3 | c.2545G>T p.G849C (on ENST00000622464; = p.G885C on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.289); catalogued as COSV52547515; called by muse, varscan2
- AGAP3 | c.2546G>T p.G849V (on ENST00000622464; = p.G885V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52547517; called by muse, mutect2, varscan2
- AIP | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as COSV54160687; called by muse, mutect2, varscan2
- ALDH1A2 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.101); catalogued as COSV51081216; called by muse, mutect2, varscan2
- ALPK2 | c.6415A>T p.K2139* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV64492947; called by muse, mutect2, varscan2
- ANO1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1185293726, COSV60284312, COSV99051395; called by muse, mutect2
- ARID1B | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51661148; called by muse, varscan2
- ARRB1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760297585, COSV63575474; called by muse, mutect2, varscan2
- ARSB | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV53723780; called by muse, mutect2, varscan2
- ATG16L1 | c.1745C>A p.A582E (on ENST00000392017 / NM_030803.7; = p.A563E on NM_017974.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV61465548, COSV61465600; called by muse, mutect2, varscan2
- ATM | c.8689G>A p.G2897S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53743524; called by muse, mutect2, varscan2
- BDP1 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV62431299; called by muse, mutect2, varscan2
- BRINP2 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV64177441; called by mutect2, varscan2
- C6 | c.2757T>A p.C919* | Nonsense Mutation (SNP) | VAF 22/153 reads (14%) | catalogued as COSV54709927; called by muse, mutect2, varscan2
- CDC20B | c.249G>T p.R83S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV57052147; called by muse, mutect2, varscan2
- CDCA7 | c.773G>A p.R258Q (on ENST00000347703 / NM_145810.3; = p.R337Q on NM_031942.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1052593698, COSV60720426; called by muse, mutect2, varscan2
- CDH10 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52580419; called by muse, mutect2, varscan2
- CDH24 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs757584877, COSV57460879; called by muse, mutect2, varscan2
- CDH9 | c.455T>G p.I152S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50283318; called by muse, mutect2, varscan2
- CFAP65 | c.5217G>T p.E1739D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1366370378, COSV58560888; called by muse, varscan2
- CFAP91 | c.1708G>T p.G570* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV56339039, COSV99847120; called by muse, mutect2, varscan2
- CIITA | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as rs868112925, COSV60857026; called by muse, mutect2, varscan2
- CILP | c.3091G>T p.G1031C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56024199; called by muse, mutect2, varscan2
- COL13A1 | c.1559A>G p.D520G (on ENST00000398978 / NM_001130103.2; = p.D463G on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV62569761; called by muse, mutect2, varscan2
- COL1A2 | c.2348C>A p.P783H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99799772; called by mutect2, varscan2
- CPLANE1 | c.9112T>G p.S3038A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV57059617; called by muse, mutect2, varscan2
- CSMD3 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52177062; called by muse, mutect2, varscan2
- CUZD1 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV59026510; called by muse, mutect2, varscan2
- CYP7A1 | c.1408A>T p.I470L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV56963491; called by muse, mutect2, varscan2
- DCAF4L2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs560566567, COSV60478605; called by muse, mutect2, varscan2
- DEPDC1B | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs866059629, COSV54010004; called by muse, mutect2, varscan2
- DIPK2A | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.953); catalogued as COSV59857269; called by muse, mutect2, varscan2
- DNAH8 | c.7608+2T>A p.X2536_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV59444234; called by muse, mutect2
- DTNA | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV51995122, COSV52002591; called by muse, mutect2, varscan2
- EPHA10 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV57623930; called by muse, mutect2, varscan2
- ERV3-1 | c.1226A>G p.N409S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99275692; called by muse, mutect2, varscan2
- ERVW-1 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV71259685; called by muse, mutect2, varscan2
- EYA4 | c.1240C>G p.R414G (on ENST00000531901 / NM_001301013.1; = p.R408G on NM_004100.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV62045783, COSV62051715; called by muse, mutect2, varscan2
- FAM83B | c.1986G>T p.R662S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60921985; called by muse, mutect2, varscan2
- FANCG | c.19T>A p.S7T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV66213726, COSV66213869; called by muse, mutect2, varscan2
- FLG | c.5710C>A p.Q1904K | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.555); catalogued as rs535039957, COSV64241684; called by muse, varscan2
- FLNB | c.5124A>C p.E1708D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55879119; called by muse, mutect2, varscan2
- GABRA2 | c.817T>C p.W273R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62914907; called by muse, mutect2, varscan2
- GABRG2 | c.1428C>G p.I476M (on ENST00000361925 / NM_001375343.1; = p.I436M on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62717922, COSV62718150; called by muse, mutect2, varscan2
- GASK1B | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV56707212; called by muse, mutect2
- GIMAP8 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV56231347; called by muse, mutect2, varscan2
- GLDC | c.2489C>A p.T830K | Missense Mutation (SNP) | VAF 107/174 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as CM061016, COSV58679063, COSV58679897; called by muse, mutect2, varscan2
- GOLGA4 | c.75G>T p.A25= | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as COSV62709319, COSV62710637; called by muse, mutect2, varscan2
- GP6 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV59977383; called by muse, mutect2, varscan2
- GPR132 | c.438C>A p.Y146* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV61677852, COSV61677919; called by muse, mutect2, varscan2
- GPR171 | c.762A>G p.I254M | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.946); catalogued as COSV56378501; called by muse, mutect2, varscan2
- GSR | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55320617; called by muse, mutect2, varscan2
- H2AC1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV51237194; called by muse, mutect2, varscan2
- HECW2 | c.3941T>A p.L1314H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53659374; called by mutect2, varscan2
- HGSNAT | c.1049A>T p.Q350L | Missense Mutation (SNP) | VAF 122/684 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52817040; called by muse, mutect2, varscan2
- HIVEP2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775033088, COSV50012224; called by muse, mutect2, varscan2
- HTR2C | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52210196; called by muse, mutect2, varscan2
- IFT81 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV54362377; called by mutect2, varscan2
- IGSF9B | c.837G>C p.R279S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1172580423, COSV58067401; called by muse, mutect2, varscan2
- IL1RAPL2 | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV61156924; called by muse, mutect2, varscan2
- INSRR | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV63873000; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1511A>T p.Q504L (on ENST00000485419 / NM_001197113.1; = p.Q428L on NM_014575.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV61844976; called by muse, mutect2
- ITGA10 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV65197329; called by muse, varscan2
- ITPR3 | c.1634A>G p.K545R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65408974; called by muse, mutect2, varscan2
- KCNK18 | c.281G>T p.W94L | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV57971759; called by muse, mutect2, varscan2
- KHDRBS3 | c.629C>A p.T210K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV63418299; called by muse, mutect2, varscan2
- KIF2A | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as rs757038674, COSV66945476; called by muse, mutect2, varscan2
- KMT2D | c.3600C>G p.I1200M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV56438909; called by muse, mutect2, varscan2
- LIG4 | c.109A>T p.R37* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV63597023; called by muse, mutect2, varscan2
- LMBRD2 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56949894; called by muse, mutect2
- LRFN5 | c.1241C>A p.T414N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV53255670; called by muse, mutect2, varscan2
- LRIT1 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV64512629; called by muse, mutect2, varscan2
- LRP1B | c.7753G>T p.D2585Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV67218195; called by muse, mutect2, varscan2
- LRRC20 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV62938110; called by muse, mutect2, varscan2
- LRRC71 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV61656210; called by mutect2, varscan2
- LRRN3 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57819562; called by muse, mutect2, varscan2
- LRRN3 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV57819570; called by muse, mutect2, varscan2
- MAGI2 | c.3365A>G p.Y1122C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV62644045; called by muse, mutect2, varscan2
- MDN1 | c.4791G>C p.K1597N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV65521446; called by muse, mutect2, varscan2
- METTL4 | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60603533; called by muse, mutect2, varscan2
- MUC5B | c.13064C>G p.S4355C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV71592013; called by muse, mutect2, varscan2
- MYO15A | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV52751208, COSV52756488; called by muse, mutect2, varscan2
- MYO16 | c.5527G>T p.G1843W | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV62750070; called by muse, mutect2, varscan2
- NEK10 | c.1502A>T p.E501V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV58283316; called by muse, mutect2, varscan2
- NELL2 | c.502T>A p.C168S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61574633; called by muse, mutect2, varscan2
- NRAP | c.3758G>C p.G1253A (on ENST00000359988 / NM_001322945.2; = p.G1218A on NM_006175.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV63490517; called by muse, mutect2, varscan2
- NRSN2 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV66526704; called by muse, mutect2
- NSUN3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757503445, COSV58935432; called by muse, mutect2, varscan2
- OR2A5 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs770043644, COSV68738717; called by muse, mutect2, varscan2
- OR2J3 | c.773C>A p.A258D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV65848976, COSV65849386; called by muse, mutect2, varscan2
- OR4A15 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.411); catalogued as rs990104819, COSV59035217; called by muse, mutect2, varscan2
- OR4C13 | c.286A>T p.M96L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV73648747; called by muse, mutect2, varscan2
- OR4D2 | c.469A>C p.I157L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV73459756, COSV73459761; called by muse, mutect2, varscan2
- OR4D6 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs749200311, COSV55659731; called by muse, mutect2, varscan2
- OR4M1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60060497, COSV60061265; called by muse, mutect2, varscan2
- OR5D18 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV61737099, COSV61737162; called by muse, mutect2, varscan2
- OR5J2 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56621183, COSV56621309; called by muse, mutect2, varscan2
- OR7A17 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV59414271; called by muse, mutect2, varscan2
- PARS2 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64883530; called by muse, mutect2, varscan2
- PCDH15 | c.5225C>T p.P1742L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV57308565; called by muse, mutect2
- PDGFC | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV56848452, COSV99925328; called by muse, mutect2, varscan2
- PDZRN3 | c.2527A>G p.S843G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55199179; called by muse, mutect2, varscan2
- POLD1 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV70955144; called by mutect2, varscan2
- PPIAL4G | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV70087042; called by muse, mutect2, varscan2
- PPM1K | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771700320, COSV55795812; called by muse, mutect2, varscan2
- PPP1R17 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV59611445, COSV59612670; called by muse, mutect2, varscan2
- PREX1 | c.2305G>C p.E769Q | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.501); catalogued as COSV64251658; called by muse, mutect2, varscan2
- PRKD1 | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59561529, COSV59568436; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1438G>C p.G480R (on ENST00000421990 / NM_001136042.2; = p.G462R on NM_025267.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV64182941; called by muse, mutect2, varscan2
- QRFPR | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as COSV57677021; called by muse, mutect2, varscan2
- RANBP17 | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV66649980; called by muse, mutect2, varscan2
- RANBP17 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV101205944, COSV66649985; called by muse, mutect2, varscan2
- RANGAP1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV62363412; called by muse, mutect2, varscan2
- RBM12B | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV67897945; called by muse, mutect2, varscan2
- RBM5 | c.1760A>G p.E587G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61737460; called by muse, mutect2
- RBMS1 | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as COSV62352975; called by muse, mutect2, varscan2
- RELN | c.4465G>C p.G1489R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59001385; called by muse, mutect2, varscan2
- RRN3 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs567466622, COSV52214448; called by muse, mutect2, varscan2
- SEMA3E | c.1737G>T p.G579= | Splice Region (SNP) | VAF 61/108 reads (56%) | catalogued as rs1348632647, COSV57089824; called by muse, mutect2, varscan2
- SHPRH | c.2950C>A p.P984T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51605664, COSV51609569; called by muse, mutect2, varscan2
- SLAIN1 | c.1470G>T p.M490I (on ENST00000466548; = p.M227I on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV57386722, COSV57389679; called by muse, mutect2, varscan2
- SLC15A2 | c.1628A>G p.Y543C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs751043994, COSV55197784; called by muse, mutect2, varscan2
- SLC1A1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52052930; called by muse, mutect2, varscan2
- SLC41A2 | c.736-1G>T p.X246_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV51604843; called by muse, mutect2, varscan2
- SNTG1 | c.1383G>C p.Q461H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as COSV52424658, COSV52442598; called by muse, mutect2, varscan2
- SPAG17 | c.1054A>T p.M352L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV60458588; called by muse, mutect2, varscan2
- SPEG | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs773563946, COSV56663336; called by mutect2, varscan2
- SRCAP | c.6439C>A p.Q2147K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV52672429; called by muse, mutect2, varscan2
- SSTR3 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1054188776, COSV100142674; called by muse, mutect2, varscan2
- STARD4 | c.46A>G p.N16D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV56967987; called by muse, mutect2, varscan2
- TAAR2 | c.308G>C p.R103T (on ENST00000367931 / NM_001033080.1; = p.R58T on NM_014626.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51578374, COSV51579074; called by muse, mutect2, varscan2
- TDRD5 | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV54242566; called by muse, mutect2, varscan2
- TET1 | c.6346A>G p.N2116D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65384715; called by muse, mutect2, varscan2
- TIGAR | c.466G>T p.G156* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV51627808; called by muse, mutect2, varscan2
- TIMP4 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55139188, COSV99826008; called by muse, mutect2, varscan2
- TLN1 | c.1236A>T p.E412D | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV59207393; called by muse, mutect2, varscan2
- TLR4 | c.1748G>T p.C583F (on ENST00000355622 / NM_138554.5; = p.C543F on NM_003266.4) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923230; called by muse, mutect2, varscan2
- TM7SF2 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54207109, COSV54207241; called by muse, mutect2, varscan2
- TMEM170B | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65157475, COSV65157523; called by muse, mutect2, varscan2
- TRIM21 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54344128; called by muse, mutect2, varscan2
- TRIM39 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV64955336; called by muse, mutect2, varscan2
- TTN | c.89841T>A p.N29947K (on ENST00000591111; = p.N22523K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | PolyPhen probably damaging (0.997); catalogued as COSV60050540; called by muse, mutect2, varscan2
- UGT1A9 | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV60838879; called by muse, mutect2, varscan2
- UNC80 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV55891057; called by muse, mutect2, varscan2
- UPP1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs541102906, COSV57977596; called by mutect2, varscan2
- VPS13B | c.3871G>C p.G1291R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV62141403; called by muse, mutect2
- WNT5A | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52837273; called by muse, mutect2, varscan2
- WTAP | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV61610085; called by muse, mutect2, varscan2
- ZCCHC7 | c.102A>T p.Q34H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV59719305; called by mutect2, varscan2
- ZHX2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV58713126; called by muse, varscan2
- ZNF536 | c.1273A>T p.N425Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV62823929; called by muse, mutect2, varscan2
- ZNF625 | c.598T>G p.L200V | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV63242100; called by muse, varscan2
- ATP6V1D | c.365_368del p.T122Ifs*2 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- EED | c.293del p.G98Efs*14 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- GPHN | c.432del p.P145Qfs*30 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- IGHV1-46 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MAT1A | c.1157del p.P386Hfs*55 | Frame Shift Del (DEL) | VAF 37/247 reads (15%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3450del p.S1152Afs*27 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- OR5L2 | c.562_563del p.A188Lfs*3 | Frame Shift Del (DEL) | VAF 25/208 reads (12%) | called by mutect2, pindel*
- OXGR1 | c.199dup p.S67Kfs*41 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- PHF11 | c.921del p.K307Nfs*55 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- PSORS1C1 | c.434del p.P145Lfs*7 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | called by mutect2, pindel, varscan2
- RASA1 | c.2729_2731del p.L910_N911delinsH | In Frame Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- SLIT2 | c.1261del p.A421Pfs*21 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3501C>G p.I1167M | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ABCA1 | c.306G>T p.V102= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV66058472, COSV66060281; called by muse, mutect2, varscan2
- ADAM29 | c.348C>A p.L116= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100822025, COSV63663486; called by mutect2, varscan2
- AKAP9 | c.7905A>G p.L2635= (on ENST00000359028; = p.L2611= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV62345909; called by muse, mutect2
- ARHGAP30 | c.60C>T p.C20= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs376993668; called by muse, mutect2, varscan2
- BDH1 | c.921C>T p.T307= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV64018479; called by muse, mutect2, varscan2
- CCN3 | c.741G>T p.R247= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV52383854; called by muse, mutect2, varscan2
- COL4A4 | c.2334G>T p.V778= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV61632076; called by muse, mutect2, varscan2
- CSMD2 | c.7002G>C p.L2334= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs756824884, COSV53911096, COSV53949807; called by muse, mutect2, varscan2
- DPP3 | c.381C>T p.I127= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as COSV64756756; called by muse, mutect2, varscan2
- F12 | c.162C>T p.H54= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs775450393, COSV53691353; called by muse, mutect2
- FBXW9 | c.1044C>T p.T348= (on ENST00000587955; = p.T328= on NM_032301.3) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV66709605; called by muse, mutect2, varscan2
- FLYWCH2 | c.108C>T p.P36= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV53558786; called by muse, mutect2, varscan2
- LRP4 | c.2997G>A p.R999= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as COSV66135768; called by muse, mutect2, varscan2
- MED27 | c.246G>A p.E82= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV99406579; called by muse, mutect2
- MMP28 | c.417G>T p.L139= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs959495139; called by mutect2, varscan2
- MUC16 | c.15216C>G p.L5072= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV67465018; called by muse, mutect2, varscan2
- OR2L2 | c.495C>A p.I165= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV63552673; called by muse, mutect2, varscan2
- OR4A15 | c.924G>A p.G308= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV59035028; called by muse, mutect2, varscan2
- OR52B2 | c.648C>A p.I216= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs1224930926, COSV73209368; called by muse, mutect2, varscan2
- OR5H15 | c.453T>G p.A151= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV62947962; called by muse, mutect2, varscan2
- OR8H3 | c.657G>A p.V219= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV57907742, COSV57908863; called by muse, mutect2, varscan2
- PARP15 | c.1671C>G p.L557= (on ENST00000464300 / NM_001113523.3; = p.L323= on NM_152615.2) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV59972620; called by muse, mutect2, varscan2
- PAX4 | c.174A>G p.L58= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV58388633; called by muse, mutect2, varscan2
- PCDHB11 | c.1890G>A p.L630= | Silent (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- PLAGL1 | c.258C>A p.P86= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99394407; called by muse, mutect2, varscan2
- PTPRC | c.1161A>C p.T387= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV61411396; called by muse, mutect2, varscan2
- PTPRD | c.2628A>G p.K876= | Silent (SNP) | VAF 173/211 reads (82%) | catalogued as COSV61945195; called by muse, mutect2, varscan2
- RBM4 | c.906A>T p.S302= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV59518808, COSV59520098; called by muse, mutect2, varscan2
- RSBN1L | c.160C>A p.R54= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58508188; called by muse, mutect2, varscan2
- SSTR3 | c.315C>A p.A105= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs914412934, COSV60729339; called by mutect2, varscan2
- TASOR2 | c.3856C>T p.L1286= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as rs1470468761, COSV60167381, COSV60167408; called by muse, mutect2, varscan2
- TENM3 | c.4527C>T p.N1509= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV69307638; called by muse, varscan2
- TLE3 | c.1455C>T p.H485= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs762068389, COSV58169350; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1461C>T p.D487= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs144166946, COSV60675790; called by muse, mutect2, varscan2
- TTN | c.54549C>T p.D18183= (on ENST00000591111; = p.D10759= on NM_003319.4) | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV60050588; called by muse, mutect2, varscan2
- XIRP2 | c.9627G>T p.T3209= (on ENST00000628543; = p.T3384= on NM_152381.6) | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV54699405; called by muse, mutect2, varscan2
- ZNF281 | c.1371A>G p.E457= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs1458218673, COSV54167081; called by muse, mutect2, varscan2
- LARP7 | c.1142+230A>G | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60520910; called by muse, mutect2, varscan2
- MIR329-1 | n.23G>T | RNA (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- PITPNC1 | c.683-5492G>A | Intron (SNP) | VAF 50/108 reads (46%) | catalogued as COSV100083466; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-87030G>T | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100324387; called by mutect2, varscan2
- RNU6-1178P | chr17:20895878 C>A | 5'Flank (SNP) | VAF 20/95 reads (21%) | catalogued as COSV60002228; called by muse, mutect2, varscan2
- SNORD64 | n.28G>C | RNA (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
